Somatic mutation profile of tumor specimen 0DETFM from CCDI case PBBPDS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.3 years (105 days).
Specimen 0DETFM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 669e2cfd-ebef-4471-b95d-be8a0028e5e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DETFG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea11eb21-1288-499a-9144-d1b5e86a0b4e

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEB6B | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 30/1070 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1438059138; called by muse, mutect2
- SPATA31D1 | c.279G>C p.R93S | Missense Mutation (SNP) | VAF 340/1037 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV61193872, COSV61193944; called by muse, mutect2, varscan2
- SCARF1 | c.791+87G>T | Intron (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
